Somatic mutation profile of tumor specimen 0DJO5E from CCDI case PBBXBJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 16.0 years (5,859 days).
Specimen 0DJO5E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8395d09-ac31-4db5-b919-474aadfba10a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710fec16-f888-4975-bac8-8e2df89b4ccf

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, 3'UTR 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 454/514 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CD27 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 114/333 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757920860, COSV56949352; called by muse, varscan2
- EIF4A1 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 252/678 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV51512516; called by muse, varscan2
- JMY | c.668C>G p.P223R | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV68660820; called by muse, varscan2
- KIF21B | c.4681C>T p.L1561F (on ENST00000422435 / NM_001252100.2; = p.L1548F on NM_017596.4) | Missense Mutation (SNP) | VAF 178/532 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774513349; called by muse, varscan2
- LUZP2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 893/2374 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61203467; called by muse, varscan2
- OR56B4 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 257/664 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV57205033; called by muse, varscan2
- PKNOX1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 192/554 reads (35%) | catalogued as COSV52338499; called by muse, varscan2
- PLA2G3 | c.1224C>A p.H408Q | Missense Mutation (SNP) | VAF 168/491 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as COSV99311437; called by muse, varscan2
- RP1 | c.2180G>T p.C727F | Missense Mutation (SNP) | VAF 761/1246 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as CX1310311; called by muse, varscan2
- SLC5A7 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 118/963 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV99886731; called by muse, varscan2
- TENM3 | c.2987C>T p.T996I | Missense Mutation (SNP) | VAF 402/1110 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs781170358; called by muse, varscan2
- THBS3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as rs144852544; called by muse, varscan2
- ZNRF4 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200385003, COSV55773789; called by muse, varscan2
- ABR | c.1454T>C p.V485A (on ENST00000302538 / NM_021962.5; = p.V448A on NM_001092.5) | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.313); called by muse, varscan2
- ACOXL | c.443T>A p.I148K | Missense Mutation (SNP) | VAF 212/648 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, varscan2
- CLDN11 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 233/752 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, varscan2
- FLRT2 | c.1552T>A p.Y518N | Missense Mutation (SNP) | VAF 224/596 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, varscan2
- MUC16 | c.7615G>T p.A2539S | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- RIF1 | c.4630G>C p.G1544R | Missense Mutation (SNP) | VAF 326/834 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SOX30 | c.972A>G p.I324M | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.145); called by muse, varscan2
- GPC1 | c.1029C>T p.C343= | Silent (SNP) | VAF 146/344 reads (42%) | catalogued as rs867054183; called by muse, varscan2
- KIR2DL3 | c.993C>T p.I331= | Silent (SNP) | VAF 396/1177 reads (34%) | catalogued as rs745904711, COSV100667910, COSV60895746; called by muse, varscan2
- PHYHD1 | c.711G>A p.L237= (on ENST00000372592 / NM_001100876.2; = p.W230* on NM_174933.4) | Silent (SNP) | VAF 60/163 reads (37%) | catalogued as rs762406223; called by muse, varscan2
- PQBP1 | c.288T>C p.N96= | Silent (SNP) | VAF 226/289 reads (78%) | catalogued as rs782360331; ClinVar: uncertain significance; called by muse, varscan2
- UPF3A | c.1350G>A p.A450= | Silent (SNP) | VAF 158/1520 reads (10%) | catalogued as rs755114249; called by muse, varscan2
- CCDC97 | c.46+53A>G | Intron (SNP) | VAF 20/101 reads (20%) | called by muse, varscan2
- CRISPLD1 | c.*36C>T | 3'UTR (SNP) | VAF 220/992 reads (22%) | catalogued as COSV100082542; called by muse, varscan2
- ELAVL2 | c.-12-2764G>T | Intron (SNP) | VAF 152/478 reads (32%) | catalogued as COSV99807171; called by muse, varscan2
- HTR2C | c.*26C>T | 3'UTR (SNP) | VAF 20/140 reads (14%) | catalogued as rs936429819, COSV52218646; called by muse, varscan2
